Gene-level copy-number profile of tumor specimen TCGA-DX-A8BG-01A from TCGA case TCGA-DX-A8BG, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 83.0 years (30,333 days).
Specimen TCGA-DX-A8BG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.0354dd0a-3de5-4926-be37-b050495fafc2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BG-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37f866be-d400-4c31-8959-664a688c7364

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1,785; copy number 2: 6,581; copy number 3: 14,595; copy number 4: 14,164; copy number 5: 10,723; copy number 6: 7,300; copy number 7: 2,089; copy number 8: 1,845; copy number 9: 358; copy number 10: 230; copy number 11: 27; copy number 13: 53; copy number 16: 2; copy number 17: 2; copy number 23: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BG-01A-12D-A416-01): tumor purity 0.31, ploidy 4.04, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,618 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–171,392,790, 1,050 genes, copy number 7–8 (broad region; genes not listed).
- chr1:181,190,471–189,814,918, 133 genes, copy number 7–23 (within-gene range 5–23) (broad region; genes not listed).
- chr1:203,765,177–204,829,274, 39 genes, copy number 7: LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1.
- chr2:84,315,108–118,110,997, 773 genes, copy number 7–11 (broad region; genes not listed).
- chr2:121,216,587–128,519,177, 94 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr2:139,668,547–139,825,877, 3 genes, copy number 8: MRPS18BP2, RPL9P13, AC078851.1.
- chr2:190,908,460–202,205,188, 182 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:27,917,753–30,008,316, 21 genes, copy number 8: AC007106.2, AC007106.1, AC093791.2, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1.
- chr7:149,003,062–150,237,608, 36 genes, copy number 7 (within-gene range 5–7): PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1, ZNF467, SSPOP, ZNF862, AC004877.2, AC004877.1, ATP6V0E2-AS1, ATP6V0E2, AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2, AC006008.1.
- chr11:46,332,905–54,693,359, 153 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr11:80,527,960–81,431,520, 6 genes, copy number 8: RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1.
- chr13:112,052,078–114,132,623, 59 genes, copy number 7 (within-gene range 4–7): AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1.
- chr14:24,809,656–28,490,362, 27 genes, copy number 7: STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3.
- chr14:43,274,824–52,952,435, 172 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:54,842,008–56,427,032, 37 genes, copy number 8: GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284.
- chr14:60,212,462–82,796,221, 484 genes, copy number 7–9 (broad region; genes not listed).
- chr15:67,542,703–68,295,862, 15 genes, copy number 7 (within-gene range 5–7): MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B.
- chr16:81,100,875–81,220,370, 1 gene, copy number 8 (within-gene range 6–8): PKD1L2.
- chr16:81,151,820–82,575,518, 28 genes, copy number 8: AC092718.9, BCO1, AC131888.1, AC009148.1, GAN, MIR4720, CMIP, AC092139.1, PPIAP51, AC092139.2, MIR7854, MIR6504, AC092135.2, AC092135.1, AC092135.3, AC099524.1, PLCG2, RN7SKP176, AC092142.2, SDR42E1, HSD17B2, AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1, RN7SKP190, AC009117.1, AC009117.2.
- chr16:82,688,931–82,727,694, 2 genes, copy number 8: MIR8058, AC099506.2.
- chr16:87,083,562–90,222,851, 128 genes, copy number 8 (broad region; genes not listed).
- chr17:7,913,324–12,790,242, 130 genes, copy number 8 (broad region; genes not listed).
- chr17:19,417,769–19,492,991, 1 gene, copy number 7 (within-gene range 6–7): AC004448.2.
- chr17:19,457,080–27,047,934, 154 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr17:70,778,604–72,237,203, 14 genes, copy number 8: AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9.
- chr17:74,541,073–77,728,559, 169 genes, copy number 7 (broad region; genes not listed).
- chr17:82,160,056–83,095,122, 49 genes, copy number 7: AC129510.2, AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, AC132872.5, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL.
- chr18:11,609,596–14,571,788, 114 genes, copy number 7 (broad region; genes not listed).
- chr18:20,946,906–26,657,401, 116 genes, copy number 8 (broad region; genes not listed).
- chr18:26,685,954–26,865,771, 6 genes, copy number 8: AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4.
- chr18:32,672,673–35,290,245, 25 genes, copy number 7 (within-gene range 6–7): KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1.
- chr18:49,036,387–49,461,347, 1 gene, copy number 7 (within-gene range 5–7): DYM.
- chr18:49,116,301–50,458,795, 41 genes, copy number 7: AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1, MYO5B, Y_RNA, RNA5SP457, AC091044.1, ADAD1P2, AC105224.1, MIR4320, RN7SL310P, CFAP53, AC090246.1, MBD1, CXXC1, AC105227.1, AC105227.2, RNA5SP458, SKA1, RPLP0P11.
- chr18:51,346,249–54,578,619, 28 genes, copy number 8 (within-gene range 5–8): LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2.
- chr18:75,642,494–75,928,004, 4 genes, copy number 8: AC090338.1, LINC01898, AC021506.1, AC021506.2.
- chr19:27,638,483–34,127,423, 139 genes, copy number 7 (broad region; genes not listed).
- chr19:36,034,984–39,738,029, 184 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,340. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
